Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7371, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7371-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

1, 5) PHARYNX, LARYNX, PHARYNGOLARYNGECTOMY: MODERATELY DIFFERENTIATED KERATINIZING SQUAMOUS CELL CARCINOMA OF THE EPIGLOTTIS, 2.3 CM IN GREATEST EXTENT, INVOLVING THE ANTERIOR COMMISSURE, RIGHT AND LEFT FALSE VOCAL FOLDS, AND THE PRE-EPIGLOTTIS, EXTENSION INTO THE EPIGLOTTIC CARTILAGE; FOCALLY INVOLVING THE SUPERIOR INKED LEFT ANTERIOR SOFT TISSUE RESECTION MARGIN, ALL OTHER MARGINS, NEGATIVE FOR MALIGNANCY (SEE COMMENT).

2) MARGIN, POSTERIOR CRICOID, EXCISION: NEGATIVE FOR MALIGNANCY.

3) MARGIN, LEFT HYPOPHARYNX, EXCISION: NEGATIVE FOR MALIGNANCY.

4) MARGIN, RIGHT HYPOPHARYNX, EXCISION: NEGATIVE FOR MALIGNANCY.

6) LYMPH NODES, LEFT NECK LEVEL 4, DISSECTION: 19 LYMPH NODES, NEGATIVE FOR MALIGNANCY.

7) LYMPH NODES, LEFT NECK LEVEL 2A, 3, DISSECTION: 43 LYMPH NODES, NEGATIVE FOR MALIGNANCY.

8) LYMPH NODES, RIGHT NECK LEVEL 2, 3, 4, DISSECTION: 1 OF 40 LYMPH NODES INVOLVED BY METASTATIC SQUAMOUS CELL CARCINOMA.

9) LYMPH NODES, LEVEL 1A, EXCISIONAL BIOPSY: 2 LYMPH NODES, NEGATIVE FOR MALIGNANCY.

COMMENT: These findings correspond to AJCC 6TH Edition Pathologic Stage III (pT3N1Mn/a).

**Electronically Signed Out by [REDACTED]

CLINICAL DATA

Clinical Features: Unspecified

Operator: [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1) epiglottis, 2) post cricoid, 3) left hypopharynx, 4) right hypopharynx, 5)

[page 2 of 4]
pharyngolaryngectomy; 6)left neck level
4; 7)left neck levels 2A, 3; 8)right neck
levels 2,3,4; 9)neck dissection level 1A

INSTRUCTIONS TO PATHOLOGIST: Frozen.

GROSS DESCRIPTION:

1) SOURCE: Epiglottis

Received fresh labeled, "epiglottis," is a 0.6 x 0.4 x 0.3 cm piece of tan-white tissue. The specimen is submitted entirely for frozen section.
Summary of sections: 1AFSC, 1/1.

2) SOURCE: Post Cricoid

The specimen labeled "post cricoid," is received fresh and is comprised of a 2.4 x 0.2 x 0.2 cm strip of pink-tan mucosa. The specimen is submitted entirely for frozen section.
Summary of sections: 2AFSC, entirely submitted, 1/1.

3) SOURCE: Left Hypopharynx

The specimen labeled "left hypopharynx," is received fresh and is comprised of a 2.7 x 0.2 x 0.2 cm strip of tan-pink mucosa. The specimen is inked black, and submitted entirely for frozen section.
Summary of sections: 3AFSC, 1/1.

4) SOURCE: Right Hypopharynx

The specimen labeled "right hypopharynx," is received fresh and is comprised of two pieces of tissue, one measuring 1.8 x 0.3 x 0.2 cm, the second measuring 1.4 x 0.2 x 0.2 cm. The first piece of tissue does not have an easily identifiable mucosal surface. The second strip of tissue does have an identifiable mucosal surface. Each of these pieces of tissue are inked blue, and the specimen is submitted entirely for frozen section.
Summary of sections: 4AFSC, entirely submitted, 2/1.

5) SOURCE: Pharyngolaryngectomy

The specimen labeled "pharyngolaryngectomy" is received fresh and is comprised of a laryngectomy with attached epiglottis, thyroid cartilage with extension of the mucosa and trachea inferior to the thyroid cartilage. The thyroid gland is not present with the specimen. The specimen measures 8.0 cm superior to inferior x 5.0 cm left to right x 4.8 cm anterior to posterior. The specimen has been opened prior to receipt along the posterior aspect. The specimen is inked as follows: anterior-orange, posterior-black, superior-yellow, inferior-green, right-red, left-blue. Examination of the specimen shows a 2.3 x 1.8 cm ulcerated lesion on the posterior face of the epiglottis present centrally, extending to the left and right (more prominently leftward), and towards the epiglottic vocal folds. The right and left superior vocal folds are involved, medially, with the left involved laterally. The anterior commissure is involved. On sectioning, the lesion penetrates 0.4 cm deep from the mucosal surface. There is a prominent 0.8 x 0.7 x 0.7 cm nodule in the left anterior

[page 3 of 4]
superior portion of the specimen abutting the anterior superior margin. There is no gross tumor involvement of the thyroid cartilage. The tumor mass has borders and comes within 0.3 cm of the hyoid bone, which is present with the specimen. The tumor mass does appear to wrap around the superior aspect of the thyroid cartilage. There is no apparent extension inferior to the vocal folds. Representative sections are submitted. Summary of sections: 5A, inferior margin, 1/1; 5B, anterior commissure, 1/1; 5C, right superior margin with epiglottis, 1/1; 5D, right medial vocal folds, 1/1; 5E, right lateral vocal folds, 1/1; 5F, right aryepiglottic mucosa, 1/1; 5G, left anterior superior margin with prominent nodule, 2/1 (single section bisected); 5H, left medial vocal fold with closest approach to hyoid bone, 1/1; 5I, left lateral vocal fold, 1/1; 5J, left aryepiglottic mucosa, 1/1; 5K, right and left soft tissue margins, 2/1; 5L, anterior and posterior soft tissue margins, 2/1. NOTE: Appropriate sections are decalcified.

6) SOURCE: Left Neck Level 4

The specimen labeled "left neck level 4" is received in saline, and is comprised of a 5.2 x 4.2 x 0.5 cm collection of fibroadipose tissue containing lymph node candidates. Lymph node candidates range in measurement from 0.3 to 0.5 cm. The specimen is dissected and 21 lymph node candidates are removed. These lymph node candidates are submitted entirely. Summary of sections: 6A, lymph node candidates, M/1; 6B, lymph node candidates, m/1; 6C, lymph node candidates, M/1.

7) SOURCE: Left Neck Levels 2A&3

The specimen labeled "left neck levels 2A, 3" is received in saline and is comprised of a 13.5 x 4.5 x 0.5 cm collection of fibroadipose tissue containing lymph nodes and vessels, with suture ties investing the vascular end. The specimen is dissected to reveal the presence of numerous lymph node candidates measuring from 0.2 to 1.0 cm in greatest extent. The lymph node candidates are submitted entirely. Summary of sections: 7A, lymph node candidates, M/1; 7B, lymph node candidates, M/1; 7C, lymph node candidates, M/1; 7D, lymph node candidates, 6/1; 7E, two lymph nodes, each bisected, one inked black, 4/1.

8) SOURCE: Right Neck Level 2,3,&4

The specimen labeled "right neck level 2, 3, 4" is received fresh and is comprised of a 15.2 x 5.2 x 0.6 cm collection of fibroadipose tissue containing lymph nodes and vessels. The specimen is dissected to reveal the presence of numerous lymph nodes measuring from 0.2 to 1.2 cm. Lymph node candidates are submitted entirely. Summary of sections: 8A, lymph node candidates, M/1; 8B, lymph node candidates, M/1; 8C, lymph node candidates, M/1; 8D, lymph node candidates, M/1; 8E, lymph node candidates, 2/1; 8F, single lymph node, bisected, 2/1.

9) SOURCE: Neck Dissection Level 1A

The specimen labeled "neck dissection level 1A" is received in saline and is comprised of a 2.5 x 2.0 x 0.5 cm collection of fibroadipose tissue containing lymph node candidates. The specimen is divided to reveal the

[page 4 of 4]
presence of possible lymph nodes measuring from 0.3 to 0.5 cm. The specimen is submitted entirely.

Summary of sections: 9A, 2/1; 9B, 2/1; 9C, 2/1.

[REDACTED]

Slides and report reviewed by Attending Pathologist.

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Epiglottis

FROZEN SECTION DIAGNOSIS: SQUAMOUS CELL CARCINOMA. [REDACTED]

2) SOURCE: Post Cricoid

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

3) SOURCE: Left Hypopharynx

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

4) SOURCE: Right Hypopharynx

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

Electronically signed by: [REDACTED]

The following special studies were performed on this case and the interpretation is incorporated in the diagnostic report above:

1xDECALCIFICATION

In some tests, analyte specific reagents (ASRs) are used. In the case of an ASR, this test was developed and its performance characteristics determined by this laboratory. It has not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

[REDACTED]

Source: NCI Genomic Data Commons file f599c998-cb52-4824-8f0b-dd8c99208ea6 (TCGA-CR-7371.D6BFEA59-7F79-4CFC-9098-E96E3407349F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).